Somatic mutation profile of tumor specimen ALCH-AE7W-TTP1-A (aliquot ALCH-AE7W-TTP1-A-1-0-D-A605-36) from ALCHEMIST case ALCH-AE7W, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.3 years (25,308 days).
Specimen ALCH-AE7W-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33163a05-eb50-4d1a-83a3-25def323a986.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE7W-NB1-A (Blood Derived Normal), aliquot ALCH-AE7W-NB1-A-1-0-D-A605-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ff3cb46-2b43-471d-aba2-376f516430b2

The open-access MAF lists 609 somatic variants for this specimen: 424 protein-altering or splice-affecting, 107 silent, 78 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 368, Silent 107, Intron 46, Nonsense Mutation 36, 3'UTR 11, Splice Site 7, 5'Flank 7, 5'UTR 7, Frame Shift Del 6, RNA 6, Splice Region 4, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIN1 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs121909274, CM074066, COSV52115811; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 122/701 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs869025608, COSV61068581, COSV61070413; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1499del p.X500_splice | Splice Site (DEL) | VAF 23/148 reads (16%) | hotspot (GDC flag); catalogued as CS011568, CS941539, COSV57296073, COSV57310062, COSV57310173; called by mutect2, pindel, varscan2
- TP53 | c.817C>A p.R273S | Missense Mutation (SNP) | VAF 145/579 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASDH | c.2557G>A p.E853K | Missense Mutation (SNP) | VAF 30/524 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV52707483; called by muse, mutect2
- ABHD16A | c.1207G>T p.V403L | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as rs769265532; called by muse, mutect2, varscan2
- AC005324.2 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 23/264 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100372129; called by muse, mutect2
- ADAMTS15 | c.792C>G p.I264M | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as COSV54510582; called by muse, mutect2, varscan2
- ADARB2 | c.2108C>A p.A703E | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67182195; called by muse, mutect2, varscan2
- AGT | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs748047212; called by muse, mutect2
- AHNAK2 | c.9095C>G p.S3032C | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1369761546; called by muse, mutect2
- ALDH16A1 | c.260G>T p.R87M | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV53193011; called by muse, mutect2, varscan2
- AMBRA1 | c.1223G>A p.R408Q (on ENST00000458649 / NM_001367468.1; = p.R318Q on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/486 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.146); catalogued as rs755304341; called by muse, mutect2
- AMER2 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV63440741; called by muse, mutect2, varscan2
- ANO4 | c.1639C>G p.Q547E (on ENST00000392977 / NM_001286615.2; = p.Q512E on NM_178826.4) | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs748300252, COSV54590877; called by muse, mutect2
- ARHGEF28 | c.4474G>A p.E1492K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs747832150; called by muse, mutect2, varscan2
- ASAP2 | c.1762G>T p.A588S | Missense Mutation (SNP) | VAF 86/427 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV55631400; called by muse, mutect2, varscan2
- B3GAT3 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 26/434 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868665260, COSV53882542; called by muse, mutect2
- BIRC6 | c.3214C>G p.Q1072E | Missense Mutation (SNP) | VAF 31/372 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV70203865; called by muse, mutect2
- BMP7 | c.1047C>G p.I349M | Missense Mutation (SNP) | VAF 29/460 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67781452; called by muse, mutect2
- C1QTNF6 | c.373A>T p.S125C | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.818); catalogued as COSV55396350; called by muse, mutect2, varscan2
- C4orf45 | c.100C>T p.H34Y | Missense Mutation (SNP) | VAF 42/309 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs751902784, COSV71700922; called by muse, mutect2, varscan2
- C7orf25 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 28/323 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.285); catalogued as COSV63273544; called by muse, mutect2
- C8orf76 | c.851C>A p.S284* | Nonsense Mutation (SNP) | VAF 24/254 reads (9%) | catalogued as COSV99414859; called by muse, mutect2
- CACNG5 | c.179G>C p.R60P | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50055478; called by muse, mutect2, varscan2
- CCDC173 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 54/840 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV69573450; called by muse, mutect2
- CCND1 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99919608; called by muse, mutect2
- CCNE2 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 96/365 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1440870539; called by muse, mutect2, varscan2
- CD300LB | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV58725139; called by muse, mutect2, varscan2
- CDH11 | c.2200G>T p.A734S | Missense Mutation (SNP) | VAF 98/684 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV51757218; called by muse, mutect2, varscan2
- CELF4 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs1485752844; called by muse, mutect2
- CEP85L | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV63821475; called by muse, varscan2
- CNTRL | c.6676C>A p.H2226N | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.156); catalogued as COSV99443809; called by muse, mutect2, varscan2
- COQ5 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 50/485 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56019104; called by muse, mutect2, varscan2
- CPE | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 40/438 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs202048102; called by muse, mutect2
- CPSF1 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs1356765308; called by muse, mutect2
- CREB3 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 23/306 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV100147688; called by muse, mutect2
- CSMD2 | c.7714G>C p.E2572Q | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.718); catalogued as COSV53911635; called by muse, mutect2, varscan2
- CSMD2 | c.3676G>A p.E1226K | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1557750224, COSV53880651; called by muse, mutect2
- CTDSPL | c.442C>T p.R148W (on ENST00000273179 / NM_001008392.2; = p.R137W on NM_005808.3) | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456114979; called by muse, mutect2, varscan2
- CTNNA1 | c.350C>G p.S117C | Missense Mutation (SNP) | VAF 38/339 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs766845544; called by muse, mutect2, varscan2
- CTNNA2 | c.1942G>C p.D648H | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV58167191; called by muse, mutect2, varscan2
- CYP2D6 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 51/571 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV100637388; called by muse, mutect2
- DAG1 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 20/162 reads (12%) | catalogued as COSV58182795; called by muse, mutect2, varscan2
- DHX30 | c.2937C>G p.I979M (on ENST00000445061 / NM_138615.3; = p.I940M on NM_014966.3) | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV53142142; called by muse, mutect2
- DNAAF2 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 32/394 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53570240; called by muse, mutect2
- DOCK2 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 23/249 reads (9%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.984); catalogued as COSV56949126; called by muse, mutect2
- EFHB | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 43/381 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.73); catalogued as rs113286461, COSV55550443; called by muse, mutect2, varscan2
- EPHB1 | c.1807C>A p.P603T | Missense Mutation (SNP) | VAF 50/392 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101212562; called by muse, mutect2, varscan2
- FAM135B | c.74G>A p.R25K | Missense Mutation (SNP) | VAF 29/303 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV50524859, COSV50537129, COSV99356718; called by muse, mutect2, varscan2
- FBXL16 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV60965035; called by muse, mutect2, varscan2
- FER1L5 | c.2807G>A p.R936H (on ENST00000623019; = p.R943H on NM_001293083.2) | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1004716219; called by muse, mutect2, varscan2
- FLG | c.5029C>T p.P1677S | Missense Mutation (SNP) | VAF 34/557 reads (6%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.608); catalogued as rs373806639, COSV64244325; called by muse, mutect2
- FLG2 | c.5399C>T p.S1800L | Missense Mutation (SNP) | VAF 46/636 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99063665; called by muse, mutect2
- FREM1 | c.1933C>G p.P645A | Missense Mutation (SNP) | VAF 48/403 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV101085214; called by muse, mutect2, varscan2
- FSIP2 | c.971G>T p.R324I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV100553472; called by muse, mutect2
- GALNT8 | c.160G>T p.G54W | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs187433578; called by muse, mutect2, varscan2
- GCNA | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 46/444 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.096); catalogued as COSV101032632; called by muse, mutect2
- GFRA2 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 55/248 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs1230458714, COSV60778060; called by muse, mutect2, varscan2
- GNE | c.2233C>A p.L745M (on ENST00000396594 / NM_001128227.3; = p.L714M on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/564 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.999); catalogued as COSV64952018; called by muse, mutect2, varscan2
- GPD1 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 18/154 reads (12%) | catalogued as COSV56549252; called by muse, mutect2, varscan2
- GRID2IP | c.2548G>A p.G850R | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as rs530515112, COSV70693309; called by muse, mutect2, varscan2
- HIVEP3 | c.5449G>A p.E1817K | Missense Mutation (SNP) | VAF 47/583 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.3); catalogued as COSV56018404; called by muse, mutect2
- IRX6 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV51861248; called by muse, mutect2, varscan2
- ITGB4 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 27/486 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs759870083; called by muse, mutect2
- JPH3 | c.895G>A p.G299S | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs532653949; called by muse, mutect2, varscan2
- KCNT2 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 21/494 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54108291, COSV99654659; called by muse, mutect2
- KEAP1 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 37/191 reads (19%) | catalogued as COSV50280201, COSV50642330; called by muse, mutect2, varscan2
- KIAA1549 | c.3829C>G p.Q1277E | Missense Mutation (SNP) | VAF 30/412 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.1); catalogued as rs756342045, COSV99650934, COSV99651957; called by muse, mutect2
- KIF1B | c.4261C>G p.L1421V (on ENST00000377086 / NM_001365952.1; = p.L1375V on NM_015074.3) | Missense Mutation (SNP) | VAF 54/626 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV55815750; called by muse, mutect2
- KIZ | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 50/762 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.081); catalogued as COSV55686616; called by muse, mutect2
- L2HGDH | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 44/668 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV104377552; called by muse, mutect2
- LAS1L | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 49/476 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV56707248; called by muse, mutect2, varscan2
- LCT | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 111/807 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51551632, COSV99930574; called by muse, mutect2, varscan2
- LMX1A | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 30/374 reads (8%) | catalogued as COSV54217553; called by muse, mutect2
- LRCH2 | c.2080C>T p.H694Y | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57753247; called by muse, mutect2, varscan2
- MGAT5 | c.2086G>C p.D696H | Missense Mutation (SNP) | VAF 22/484 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.667); catalogued as COSV56096129; called by muse, mutect2
- MLXIP | c.390C>G p.F130L | Missense Mutation (SNP) | VAF 40/456 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as rs761246230; called by muse, mutect2
- MOB3A | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs201880293, COSV63865634; called by muse, mutect2, varscan2
- MYH7 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 74/320 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs45511396; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOD1 | c.188C>G p.S63W | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as rs147517396, CM162809; called by muse, mutect2
- NCKAP1L | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 70/454 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV53204580; called by muse, mutect2, varscan2
- NDUFS2 | c.1336G>T p.D446Y | Missense Mutation (SNP) | VAF 47/552 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM0911009, COSV57154178; called by muse, mutect2
- NFATC1 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53696445; called by muse, mutect2, varscan2
- NLRP12 | c.2142C>A p.N714K | Missense Mutation (SNP) | VAF 79/471 reads (17%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.811); catalogued as COSV60743776, COSV60746036; called by muse, mutect2, varscan2
- NREP | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 49/367 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV67401246; called by muse, mutect2, varscan2
- NUDT5 | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 63/428 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1205789048; called by muse, mutect2, varscan2
- OBSCN | c.8511G>T p.W2837C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV52787542; called by muse, mutect2, varscan2
- OR14K1 | c.835G>C p.A279P | Missense Mutation (SNP) | VAF 74/765 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs367970677, COSV99314974; called by muse, mutect2
- OR2AK2 | c.64T>C p.W22R | Missense Mutation (SNP) | VAF 74/331 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1375556879; called by muse, mutect2, varscan2
- OR4C15 | c.244G>T p.V82L (on ENST00000314644; = p.V28L on NM_001001920.2) | Missense Mutation (SNP) | VAF 71/404 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.065); catalogued as rs1364452843, COSV100116182, COSV58956392; called by muse, mutect2, varscan2
- OR52J3 | c.244C>G p.R82G | Missense Mutation (SNP) | VAF 38/681 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV100984961, COSV66746341; called by muse, mutect2
- PAK5 | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 38/292 reads (13%) | catalogued as COSV62020360; called by muse, mutect2, varscan2
- PCDHA10 | c.1870G>C p.G624R | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV56524296; called by muse, mutect2, varscan2
- PCDHB15 | c.1158G>C p.Q386H | Missense Mutation (SNP) | VAF 17/207 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as COSV50862022, COSV99179089; called by muse, mutect2
- PEX7 | c.508T>G p.C170G | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs373624730; called by muse, mutect2, varscan2
- PHACTR2 | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs754354729, COSV99990981; called by muse, mutect2, varscan2
- PIGO | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs750419706; called by muse, mutect2, varscan2
- PNKP | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 36/406 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs773641701, COSV55587833; ClinVar: uncertain significance; called by muse, mutect2
- POLDIP2 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.02); catalogued as rs1310596700; called by muse, mutect2, varscan2
- POM121L12 | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as rs1403727197, COSV68692383; called by muse, mutect2, varscan2
- POM121L2 | c.813G>C p.K271N | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66276138; called by muse, mutect2
- PPP1R21 | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 70/922 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.329); catalogued as rs574794078, COSV54281852, COSV99682477; called by muse, mutect2
- PRKCZ | c.436C>G p.Q146E | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.103); catalogued as COSV101057892; called by muse, mutect2, varscan2
- PTPN3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 31/431 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99355294; called by muse, mutect2
- PTPN7 | c.817G>C p.E273Q (on ENST00000495688; = p.E312Q on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV100459992; called by muse, mutect2
- PTPRO | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 57/362 reads (16%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs368231577, COSV99842037; called by muse, mutect2, varscan2
- PTPRT | c.334C>A p.R112S | Missense Mutation (SNP) | VAF 47/444 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.851); catalogued as COSV62009838; called by muse, mutect2, varscan2
- PXDNL | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs936865843, COSV62476590; called by muse, mutect2
- RERGL | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs762163321; called by muse, mutect2, varscan2
- RIMS2 | c.2500-2A>G p.X834_splice (on ENST00000666250 / NM_001348490.2; = p.X642_splice on NM_014677.5 and 7 other RefSeq transcripts) | Splice Site (SNP) | VAF 28/150 reads (19%) | catalogued as COSV51664182; called by mutect2, varscan2
- RTN3 | c.2565G>C p.K855N (on ENST00000377819 / NM_001265589.2; = p.K59N on NM_006054.4) | Missense Mutation (SNP) | VAF 39/379 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58028763; called by muse, mutect2, varscan2
- RXFP3 | c.256G>C p.V86L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as COSV57503814, COSV57509176; called by muse, mutect2, varscan2
- SACS | c.10466C>T p.S3489F | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV104428852; called by muse, mutect2
- SACS | c.6742G>T p.A2248S | Missense Mutation (SNP) | VAF 129/758 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as rs371943840; called by muse, mutect2, varscan2
- SDK1 | c.4072C>G p.R1358G | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs750782781; called by muse, mutect2, varscan2
- SEMA3D | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 25/224 reads (11%) | catalogued as rs1337694015, COSV99406651; called by muse, varscan2
- SIGLEC9 | c.1122G>T p.R374S | Missense Mutation (SNP) | VAF 33/382 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV51588242; called by muse, mutect2
- SIM1 | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV104368321; called by muse, mutect2, varscan2
- SLC16A3 | c.816C>G p.F272L | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.246); catalogued as COSV66429026; called by muse, mutect2, varscan2
- SLC8A1 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 36/616 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV60486006; called by muse, mutect2
- SNTG1 | c.468T>C p.C156= | Splice Region (SNP) | VAF 82/417 reads (20%) | catalogued as COSV99384458; called by muse, mutect2, varscan2
- SOCS4 | c.989C>G p.S330C | Missense Mutation (SNP) | VAF 75/440 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369356534; called by muse, mutect2, varscan2
- SPG11 | c.2274G>C p.K758N | Missense Mutation (SNP) | VAF 47/412 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.131); catalogued as COSV55992023; called by muse, varscan2
- ST6GAL1 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 39/394 reads (10%) | PolyPhen probably damaging (0.969); catalogued as rs771215054; called by muse, mutect2
- STARD9 | c.10189C>T p.H3397Y | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.16); catalogued as rs567445149; called by muse, mutect2, varscan2
- STK11 | c.140del p.G47Afs*4 | Frame Shift Del (DEL) | VAF 46/251 reads (18%) | catalogued as COSV100481053; called by mutect2, pindel, varscan2
- SYNPO | c.383G>C p.R128T | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV67785142; called by muse, mutect2, varscan2
- TAP1 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 92/1088 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs777683307, COSV100841206; called by muse, mutect2
- TBX18 | c.1358G>T p.R453M | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV63738627; called by muse, mutect2, varscan2
- TDRKH | c.1669G>T p.D557Y | Missense Mutation (SNP) | VAF 22/644 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100162724; called by muse, mutect2
- TEKT4 | c.1133C>G p.A378G | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV54623900; called by muse, mutect2, varscan2
- TLK2 | c.1506G>C p.E502D (on ENST00000326270 / NM_001284333.2; = p.E480D on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.981); catalogued as COSV100408649, COSV58300214; called by muse, mutect2
- TLN2 | c.1651G>C p.D551H | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV60896231; called by muse, mutect2
- TMEM120A | c.161A>G p.Q54R | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1312323786; called by muse, mutect2, varscan2
- TMEM53 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs142353018; called by muse, mutect2, varscan2
- TMEM59L | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as COSV53241460; called by muse, mutect2, varscan2
- TMEM63B | c.2273G>T p.R758L | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs1221158138, COSV52477624; called by muse, mutect2, varscan2
- TNS3 | c.2780C>T p.S927F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs1378152014; called by muse, mutect2, varscan2
- TNXB | c.3997G>A p.E1333K (on ENST00000647633; = p.E1086K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.543); catalogued as rs766226155; called by muse, mutect2
- TRHDE | c.1429C>A p.L477I | Missense Mutation (SNP) | VAF 136/471 reads (29%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.542); catalogued as rs1043563655, COSV53868473; called by muse, mutect2, varscan2
- TRPC4AP | c.473-2A>C p.X158_splice | Splice Site (SNP) | VAF 36/307 reads (12%) | catalogued as COSV99327870; called by muse, mutect2, varscan2
- TSGA10 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs1464264799; called by muse, mutect2
- VAV2 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 71/354 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64080777; called by muse, mutect2, varscan2
- VRK2 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 47/449 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60875217; called by muse, mutect2, varscan2
- VWA7 | c.2152C>T p.Q718* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV65173741; called by muse, mutect2, varscan2
- VXN | c.106C>G p.Q36E | Missense Mutation (SNP) | VAF 30/642 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV100559874, COSV59686307; called by muse, mutect2
- ZNF521 | c.2858T>A p.L953Q | Missense Mutation (SNP) | VAF 56/339 reads (17%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.925); catalogued as COSV100832890; called by muse, mutect2, varscan2
- ZNF771 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV60008756; called by muse, mutect2
- ZNF774 | c.973G>T p.G325W | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100586528; called by muse, mutect2, varscan2
- ABCC9 | c.147G>T p.W49C | Missense Mutation (SNP) | VAF 86/431 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ACSF2 | c.1188C>G p.I396M | Missense Mutation (SNP) | VAF 22/339 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.209); called by muse, mutect2
- ACTN4 | c.2008G>C p.E670Q | Missense Mutation (SNP) | VAF 30/410 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, mutect2
- ADAM33 | c.1188C>A p.F396L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- ADAMTS13 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 29/145 reads (20%) | called by muse, mutect2, varscan2
- ADGRF3 | c.142del p.L48* | Frame Shift Del (DEL) | VAF 29/192 reads (15%) | called by mutect2, pindel, varscan2
- ADGRG1 | c.488-1G>T p.X163_splice | Splice Site (SNP) | VAF 33/178 reads (19%) | called by muse, mutect2, varscan2
- ADGRV1 | c.6909G>C p.L2303F | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- AGBL2 | c.161G>T p.C54F | Missense Mutation (SNP) | VAF 52/447 reads (12%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGFG1 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 103/561 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- AKR1C1 | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 46/432 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ALPK1 | c.2003A>C p.Q668P | Missense Mutation (SNP) | VAF 68/558 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD18B | c.1528A>G p.T510A | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- ANO5 | c.109A>T p.T37S | Missense Mutation (SNP) | VAF 73/907 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- AP2M1 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP3M1 | c.794G>T p.S265I | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- ARHGAP5 | c.3032G>A p.R1011K | Missense Mutation (SNP) | VAF 38/412 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2
- ASPM | c.452G>T p.W151L | Missense Mutation (SNP) | VAF 33/292 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP12A | c.2336A>C p.E779A | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AURKB | c.45G>C p.Q15H | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.125); called by muse, mutect2
- BEND2 | c.2342C>A p.P781Q | Missense Mutation (SNP) | VAF 97/512 reads (19%) | SIFT tolerated, low confidence (0.41); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- BEST1 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 23/296 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.518); called by muse, mutect2
- BICRAL | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 42/448 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- BIRC6 | c.10643C>G p.S3548* | Nonsense Mutation (SNP) | VAF 37/319 reads (12%) | called by muse, mutect2, varscan2
- BMP5 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 113/658 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- C10orf53 | c.226G>T p.G76C | Missense Mutation (SNP) | VAF 69/290 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C17orf50 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2
- CACNA1B | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2
- CAMKK2 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBWD2 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 62/1052 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.022); called by muse, mutect2
- CCDC114 | c.615G>C p.Q205H | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- CCDC150 | c.1804-1G>T p.X602_splice | Splice Site (SNP) | VAF 49/286 reads (17%) | called by muse, mutect2, varscan2
- CCDC168 | c.2928G>T p.M976I | Missense Mutation (SNP) | VAF 46/241 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC181 | c.992C>G p.S331* | Nonsense Mutation (SNP) | VAF 38/382 reads (10%) | called by muse, mutect2
- CDHR2 | c.1834G>C p.E612Q | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.056); called by mutect2, varscan2
- CHRND | c.1411C>A p.R471S | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CNGA3 | c.1821G>C p.M607I | Missense Mutation (SNP) | VAF 74/896 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.031); called by muse, mutect2
- CNTNAP5 | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- COL4A1 | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 90/418 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); called by muse, varscan2
- COL4A2 | c.3367G>C p.E1123Q | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- CORO2B | c.1348C>G p.R450G | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- CPT1C | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.337); called by muse, mutect2
- CPTP | c.632T>G p.L211R | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CR2 | c.2082T>A p.H694Q | Missense Mutation (SNP) | VAF 107/790 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); called by muse, varscan2
- CREBBP | c.1999G>T p.E667* | Nonsense Mutation (SNP) | VAF 28/426 reads (7%) | called by muse, mutect2
- CRNN | c.864G>C p.Q288H | Missense Mutation (SNP) | VAF 20/426 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- CSMD3 | c.916T>G p.W306G | Missense Mutation (SNP) | VAF 103/539 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CSNK1A1 | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 19/396 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CTDSPL | c.443G>T p.R148L (on ENST00000273179 / NM_001008392.2; = p.R137L on NM_005808.3) | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CTR9 | c.1010C>G p.S337* | Nonsense Mutation (SNP) | VAF 32/360 reads (9%) | called by muse, mutect2
- CYP11B1 | c.549C>A p.S183R | Missense Mutation (SNP) | VAF 30/461 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2
- DCAF17 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 116/932 reads (12%) | called by muse, mutect2, varscan2
- DCAF5 | c.2461G>C p.E821Q | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); called by muse, mutect2
- DCAF5 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2
- DCAF6 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 54/369 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DDX56 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 19/290 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, mutect2
- DDX59 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 28/525 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); called by muse, mutect2
- DMP1 | c.933A>T p.R311S | Missense Mutation (SNP) | VAF 60/380 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- DMRTA1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 80/401 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH11 | c.5661G>C p.M1887I | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2
- DNAJA2 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 37/540 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2
- DNMT3A | c.1567G>C p.E523Q | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- DPF3 | c.350C>G p.T117R | Missense Mutation (SNP) | VAF 41/331 reads (12%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- EIF4G3 | c.3303C>G p.F1101L | Missense Mutation (SNP) | VAF 23/452 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.08); called by muse, mutect2
- ELAVL3 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.247); called by mutect2, varscan2
- EMILIN1 | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ENKD1 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ETF1 | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ETV1 | c.1231G>A p.V411I | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM171A1 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.383); called by muse, mutect2
- FCGBP | c.6952C>T p.Q2318* | Nonsense Mutation (SNP) | VAF 33/295 reads (11%) | called by muse, mutect2, varscan2
- FGFBP1 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGFBP1 | c.490G>C p.E164Q | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- FNIP2 | c.208C>G p.Q70E | Missense Mutation (SNP) | VAF 33/553 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.048); called by muse, mutect2
- FSIP2 | c.15793G>C p.E5265Q | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- GARS1 | c.306G>C p.K102N | Missense Mutation (SNP) | VAF 82/1107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GJA5 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 30/500 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- GJC3 | c.42C>A p.S14R | Missense Mutation (SNP) | VAF 70/531 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- GLG1 | c.3072A>T p.Q1024H | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- GNGT1 | c.143C>A p.S48Y | Missense Mutation (SNP) | VAF 39/306 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- GPLD1 | c.1579G>C p.E527Q | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.031); called by muse, mutect2
- GPR52 | c.974G>T p.R325L | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); called by muse, mutect2
- GRIN2C | c.1400G>C p.R467T | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.43); called by muse, mutect2
- GRM7 | c.1792G>T p.A598S | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- HAUS6 | c.673A>T p.S225C | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- HDAC6 | c.1000-3C>T | Splice Region (SNP) | VAF 23/162 reads (14%) | called by muse, mutect2, varscan2
- HDAC9 | c.2315A>G p.N772S | Missense Mutation (SNP) | VAF 65/357 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HHAT | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); called by muse, mutect2
- HMCN1 | c.14047G>A p.D4683N | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- HNF4A | c.428G>A p.S143N | Missense Mutation (SNP) | VAF 99/542 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXA13 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- HS3ST5 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.14); called by muse, mutect2
- HSFX1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 42/461 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2
- HTR1D | c.752C>G p.S251C | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- HYDIN | c.14062G>C p.E4688Q | Missense Mutation (SNP) | VAF 21/526 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- IFT172 | c.2191A>C p.K731Q | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- IGKV2D-28 | c.6G>T p.R2S | Missense Mutation (SNP) | VAF 34/418 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, varscan2
- IGSF22 | c.571A>G p.M191V | Missense Mutation (SNP) | VAF 61/327 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- IKBKE | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL20RA | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- INPP4B | c.2070G>C p.K690N | Missense Mutation (SNP) | VAF 34/616 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.208); called by muse, mutect2
- IPPK | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2
- IQSEC1 | c.2164G>T p.V722L | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- JPH2 | c.558C>A p.D186E | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.031); called by muse, varscan2
- KCNMA1 | c.3334G>T p.D1112Y (on ENST00000286628 / NM_001161352.2; = p.D1054Y on NM_002247.4) | Missense Mutation (SNP) | VAF 63/408 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- KCNT1 | c.225G>C p.E75D (on ENST00000488444; = p.E94D on NM_020822.3) | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.217); called by muse, mutect2
- KIAA0586 | c.4121C>G p.S1374* (on ENST00000619416 / NM_001244190.2; = p.S1313* on NM_014749.5) | Nonsense Mutation (SNP) | VAF 28/344 reads (8%) | called by muse, mutect2
- KIAA1109 | c.8035C>G p.H2679D | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- KIF1B | c.2560G>C p.E854Q (on ENST00000377086 / NM_001365952.1; = p.E808Q on NM_015074.3) | Missense Mutation (SNP) | VAF 52/971 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.936); called by muse, mutect2
- KIF21B | c.2010G>T p.K670N | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KLHL11 | c.929G>T p.R310M | Missense Mutation (SNP) | VAF 105/784 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KLHL15 | c.1397dup p.N466Kfs*6 | Frame Shift Ins (INS) | VAF 66/465 reads (14%) | called by mutect2, pindel, varscan2
- KLHL7 | c.1424G>T p.G475V (on ENST00000339077 / NM_001031710.3; = p.G427V on NM_018846.5) | Missense Mutation (SNP) | VAF 136/839 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- KNTC1 | c.4210G>T p.D1404Y | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2
- LAMA2 | c.2538G>T p.R846S | Missense Mutation (SNP) | VAF 72/608 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- LNPEP | c.2218G>T p.G740C | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, varscan2
- LOXHD1 | c.1749C>A p.D583E | Missense Mutation (SNP) | VAF 58/432 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRBA | c.3251C>G p.S1084C | Missense Mutation (SNP) | VAF 25/440 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); called by muse, mutect2
- LRP8 | c.883+1G>T p.X295_splice | Splice Site (SNP) | VAF 23/95 reads (24%) | called by muse, mutect2, varscan2
- LRRC32 | c.996C>A p.D332E | Missense Mutation (SNP) | VAF 44/292 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC63 | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 74/408 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- LRRN3 | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 91/662 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- LUZP1 | c.2527G>C p.E843Q | Missense Mutation (SNP) | VAF 39/418 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LUZP1 | c.2122G>C p.D708H | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2
- MACF1 | c.11599del p.L3867Wfs*8 (on ENST00000372915; = p.L1800Wfs*8 on NM_012090.5) | Frame Shift Del (DEL) | VAF 114/637 reads (18%) | called by mutect2, pindel, varscan2
- MACF1 | c.16675C>G p.Q5559E (on ENST00000372915; = p.Q3601E on NM_012090.5) | Missense Mutation (SNP) | VAF 101/773 reads (13%) | called by muse, mutect2, varscan2
- MACF1 | c.21997G>A p.D7333N (on ENST00000372915; = p.D5378N on NM_012090.5) | Missense Mutation (SNP) | VAF 31/414 reads (7%) | called by muse, mutect2
- MAGEF1 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2
- MAN1A2 | c.1465G>C p.E489Q | Missense Mutation (SNP) | VAF 35/492 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.113); called by muse, mutect2
- MAP4K3 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 23/372 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2
- MATN2 | c.1798G>C p.E600Q | Missense Mutation (SNP) | VAF 22/311 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.025); called by muse, mutect2
- MCM6 | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 57/561 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- MEPCE | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 13/195 reads (7%) | called by muse, mutect2
- MLXIPL | c.2155G>A p.D719N | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- MMP16 | c.524T>A p.L175* | Nonsense Mutation (SNP) | VAF 97/516 reads (19%) | called by muse, mutect2, varscan2
- MMP3 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 89/567 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MROH2B | c.526A>G p.R176G | Missense Mutation (SNP) | VAF 55/356 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- MROH7 | c.983C>T p.T328I | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.465); called by muse, mutect2
- MSRB3 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 20/133 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MTG2 | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- MUC4 | c.1673C>A p.T558K | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- MYBPH | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 36/436 reads (8%) | called by muse, mutect2
- MYO3A | c.1930G>C p.D644H | Missense Mutation (SNP) | VAF 60/916 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2
- MYT1L | c.776G>C p.R259T | Missense Mutation (SNP) | VAF 36/384 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NCDN | c.2182G>C p.E728Q | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.435); called by muse, mutect2
- NCLN | c.1338G>T p.Q446H | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- NEDD4 | c.1174A>G p.T392A | Missense Mutation (SNP) | VAF 52/323 reads (16%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEK9 | c.1596G>C p.L532F | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.382); called by muse, mutect2
- NEUROD1 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 34/397 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); called by muse, mutect2
- NFXL1 | c.2341G>C p.E781Q | Missense Mutation (SNP) | VAF 38/617 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.013); called by muse, mutect2
- NKX1-2 | c.325C>A p.R109S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NMI | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 56/680 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- NOD2 | c.2338G>T p.A780S | Missense Mutation (SNP) | VAF 123/732 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NONO | c.201G>C p.E67D | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- NPIPB4 | c.446T>A p.V149E | Missense Mutation (SNP) | VAF 78/1628 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2
- NUP214 | c.2266G>C p.E756Q | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2
- NXF1 | c.1526C>G p.S509C | Missense Mutation (SNP) | VAF 11/253 reads (4%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.905); called by muse, mutect2
- OBSCN | c.14974G>C p.E4992Q | Missense Mutation (SNP) | VAF 47/355 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- OBSCN | c.15848A>T p.K5283M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, varscan2
- OBSL1 | c.1718G>T p.G573V | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR11H1 | c.528C>A p.N176K | Missense Mutation (SNP) | VAF 46/356 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); called by mutect2, varscan2
- OSTF1 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 43/540 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- OTOP3 | c.1512G>T p.W504C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- OVCH1 | c.2525G>T p.W842L | Missense Mutation (SNP) | VAF 82/409 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PAPPA2 | c.124C>G p.Q42E | Missense Mutation (SNP) | VAF 17/391 reads (4%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); called by muse, mutect2
- PCDHA10 | c.889A>T p.R297W | Missense Mutation (SNP) | VAF 34/336 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- PDCD10 | c.624C>G p.F208L | Missense Mutation (SNP) | VAF 72/926 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2
- PGGT1B | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 17/365 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.358); called by muse, mutect2
- PIK3R5 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHA7 | c.164-6C>T | Splice Region (SNP) | VAF 27/211 reads (13%) | called by muse, mutect2, varscan2
- PLEKHB2 | c.884C>A p.P295H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | PolyPhen possibly damaging (0.893); called by muse, mutect2
- POGK | c.1682A>G p.E561G | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- POLE2 | c.56T>G p.L19W | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- POMZP3 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 59/442 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- POPDC3 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2, varscan2
- POU2F2 | c.1009G>C p.E337Q (on ENST00000526816 / NM_001207025.3; = p.E321Q on NM_002698.5) | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PRDM4 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); called by muse, mutect2
- PRKCG | c.1009T>A p.C337S | Missense Mutation (SNP) | VAF 64/408 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRMT5 | c.1697-1G>A p.X566_splice | Splice Site (SNP) | VAF 52/430 reads (12%) | called by muse, mutect2, varscan2
- PRPF39 | c.627G>A p.W209* | Nonsense Mutation (SNP) | VAF 57/442 reads (13%) | called by muse, mutect2, varscan2
- PTPN12 | c.2147del p.L716* | Frame Shift Del (DEL) | VAF 32/263 reads (12%) | called by mutect2, pindel, varscan2
- PTPN18 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PTPRQ | c.3785C>A p.A1262D (on ENST00000616559; = p.A1220D on NM_001145026.2) | Missense Mutation (SNP) | VAF 93/424 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- PTPRZ1 | c.3475G>A p.E1159K | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PWWP3B | c.1855C>T p.Q619* | Nonsense Mutation (SNP) | VAF 26/257 reads (10%) | called by muse, mutect2, varscan2
- PYGO2 | c.953C>G p.S318C | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- QRICH2 | c.4774G>A p.E1592K | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); called by muse, mutect2
- RAB6D | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 35/713 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.091); called by muse, mutect2
- RADIL | c.2377G>A p.D793N | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2
- RASA3 | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- RBSN | c.2254G>C p.D752H | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- RCAN2 | c.186C>A p.C62* | Nonsense Mutation (SNP) | VAF 81/436 reads (19%) | called by muse, mutect2, varscan2
- REN | c.961T>C p.Y321H | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RGS13 | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 25/387 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- RINT1 | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 35/455 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.028); called by muse, mutect2
- RPRD2 | c.2010G>A p.M670I | Missense Mutation (SNP) | VAF 24/441 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.438); called by muse, mutect2
- RSPO1 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.033); called by muse, mutect2
- RUSC2 | c.2743G>C p.D915H | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- SHCBP1 | c.686G>C p.R229T | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SIGLEC12 | c.1456G>T p.G486* (on ENST00000291707 / NM_053003.4; = p.G368* on NM_033329.2) | Nonsense Mutation (SNP) | VAF 18/188 reads (10%) | called by mutect2, varscan2
- SIGLECL1 | c.349C>A p.Q117K | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- SIPA1L3 | c.483G>T p.R161S | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SKOR2 | c.1307del p.G436Afs*60 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by pindel, varscan2
- SLC17A7 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- SLC19A1 | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC38A9 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 98/712 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC6A1 | c.1120C>A p.Q374K | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SLCO4A1 | c.1856G>A p.W619* | Nonsense Mutation (SNP) | VAF 33/332 reads (10%) | called by muse, mutect2, varscan2
- SLIT2 | c.285A>T p.E95D | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SOCS4 | c.700A>C p.I234L | Missense Mutation (SNP) | VAF 52/399 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPATA31A3 | c.2044C>G p.L682V | Missense Mutation (SNP) | VAF 52/329 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- SPATA31D4 | c.2476G>A p.A826T | Missense Mutation (SNP) | VAF 52/314 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.97); called by mutect2, varscan2
- SPIC | c.136C>T p.H46Y | Missense Mutation (SNP) | VAF 38/393 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2
- SRP72 | c.642+5G>C | Splice Region (SNP) | VAF 45/265 reads (17%) | called by muse, mutect2, varscan2
- SRRD | c.888C>G p.H296Q | Missense Mutation (SNP) | VAF 41/584 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2
- SRSF11 | c.174G>C p.K58N | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.022); called by muse, mutect2
- SRSF4 | c.1369G>C p.E457Q | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.212); called by muse, mutect2
- ST8SIA3 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 33/298 reads (11%) | PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- STAB2 | c.4282G>A p.D1428N | Missense Mutation (SNP) | VAF 67/470 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- SWT1 | c.1628T>A p.V543E | Missense Mutation (SNP) | VAF 49/321 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- SYNE1 | c.23942G>C p.R7981T (on ENST00000367255 / NM_182961.4; = p.R7910T on NM_033071.3) | Missense Mutation (SNP) | VAF 89/1118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TAS1R1 | c.2012A>G p.H671R | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D15 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 31/456 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- TCP1 | c.1576C>T p.R526* | Nonsense Mutation (SNP) | VAF 52/546 reads (10%) | called by muse, mutect2
- TCTN2 | c.297G>C p.K99N | Missense Mutation (SNP) | VAF 50/436 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDRD15 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 16/422 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TDRD9 | c.2756A>C p.D919A | Missense Mutation (SNP) | VAF 91/463 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TIAM1 | c.3561C>G p.I1187M | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TJP1 | c.2509A>T p.S837C | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLL2 | c.2624C>T p.S875L | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TLR6 | c.535A>T p.R179* | Nonsense Mutation (SNP) | VAF 35/197 reads (18%) | called by muse, mutect2, varscan2
- TLX3 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- TMCC1 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- TMED4 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 33/271 reads (12%) | called by muse, mutect2, varscan2
- TMEM270 | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.047); called by muse, varscan2
- TNXB | c.7021G>A p.E2341K (on ENST00000647633; = p.E2094K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.131); called by muse, mutect2
- TPR | c.3068G>C p.R1023T | Missense Mutation (SNP) | VAF 45/288 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- TPR | c.1528G>T p.A510S | Missense Mutation (SNP) | VAF 60/523 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- TRAPPC11 | c.1684C>G p.Q562E | Missense Mutation (SNP) | VAF 36/440 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.01); called by muse, mutect2
- TRIM9 | c.1245G>C p.L415F | Missense Mutation (SNP) | VAF 56/482 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRO | c.2105G>A p.R702K | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- TRPM2 | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TTC26 | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTF2 | c.555G>C p.K185N | Missense Mutation (SNP) | VAF 45/416 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TTN | c.43289C>G p.S14430* (on ENST00000591111; = p.S7006* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 17/443 reads (4%) | called by muse, mutect2
- TTN | c.19765G>T p.V6589L (on ENST00000591111; = p.V5662L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/207 reads (6%) | PolyPhen benign (0.047); called by muse, mutect2
- TTN | c.10552del p.D3518Mfs*7 (on ENST00000591111; = p.D3472Mfs*7 on NM_003319.4) | Frame Shift Del (DEL) | VAF 117/898 reads (13%) | called by mutect2, pindel, varscan2
- TUBB4A | c.504C>A p.S168R | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUFT1 | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 36/581 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.988); called by muse, mutect2
- UIMC1 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 63/383 reads (16%) | called by muse, mutect2, varscan2
- ULK1 | c.1574G>A p.G525E | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- UNC79 | c.1299C>G p.N433K (on ENST00000393151 / NM_001346218.2; = p.N256K on NM_020818.5) | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2
- USP7 | c.1541A>C p.Y514S | Missense Mutation (SNP) | VAF 100/483 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VWF | c.3623C>G p.S1208* | Nonsense Mutation (SNP) | VAF 60/556 reads (11%) | called by muse, mutect2, varscan2
- WDCP | c.1018C>G p.L340V | Missense Mutation (SNP) | VAF 21/292 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WDFY3 | c.9738G>C p.M3246I | Missense Mutation (SNP) | VAF 63/445 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR62 | c.1775G>C p.R592T | Missense Mutation (SNP) | VAF 34/365 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.257); called by muse, mutect2
- WIPF3 | c.1061C>G p.S354C | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.52); called by muse, mutect2
- WIPI2 | c.1192C>G p.Q398E | Missense Mutation (SNP) | VAF 17/288 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.248); called by muse, mutect2
- XIRP2 | c.5056G>T p.E1686* (on ENST00000628543; = p.E1861* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 48/472 reads (10%) | called by muse, mutect2, varscan2
- ZFP90 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); called by muse, mutect2
- ZKSCAN2 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 33/424 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.626); called by muse, mutect2
- ZNF135 | c.1636G>T p.G546* (on ENST00000313434 / NM_001289401.2; = p.G558* on NM_003436.4) | Nonsense Mutation (SNP) | VAF 46/250 reads (18%) | called by muse, mutect2, varscan2
- ZNF397 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 26/450 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2
- ZNF583 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF585B | c.1789C>G p.Q597E | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ZNF638 | c.5308G>A p.E1770K | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF658 | c.1956C>A p.H652Q | Missense Mutation (SNP) | VAF 137/920 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF774 | c.972C>A p.C324* | Nonsense Mutation (SNP) | VAF 34/178 reads (19%) | called by muse, mutect2, varscan2
- ZNF804A | c.2627G>A p.R876K | Missense Mutation (SNP) | VAF 82/531 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN1 | c.608C>A p.S203Y | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.211); called by muse, mutect2
- ZSCAN18 | c.942dup p.A315Cfs*9 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by mutect2, varscan2
- ZW10 | c.2224G>T p.A742S | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, varscan2
- ZXDC | c.191C>A p.P64Q | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ACLY | c.726C>T p.F242= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as rs782400219, COSV61249818; called by muse, mutect2
- ACOT11 | c.732C>A p.A244= | Silent (SNP) | VAF 24/102 reads (24%) | called by muse, varscan2
- ADGRD2 | c.2379C>T p.A793= | Silent (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- AHCYL2 | c.528G>A p.Q176= | Silent (SNP) | VAF 116/649 reads (18%) | catalogued as rs1213330218, COSV61485694; called by muse, varscan2
- AKAP12 | c.3772C>T p.L1258= | Silent (SNP) | VAF 31/369 reads (8%) | catalogued as COSV53577637, COSV99482812; called by muse, mutect2
- ALPP | c.507C>T p.T169= | Silent (SNP) | VAF 35/274 reads (13%) | called by muse, mutect2, varscan2
- ANK2 | c.4279C>A p.R1427= | Silent (SNP) | VAF 102/741 reads (14%) | catalogued as COSV100001534; called by muse, mutect2, varscan2
- ANKRD36 | c.3402C>T p.I1134= | Silent (SNP) | VAF 35/338 reads (10%) | called by muse, mutect2, varscan2
- CCDC114 | c.708G>A p.P236= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs148382103; called by muse, mutect2
- CDK8 | c.273G>A p.R91= | Silent (SNP) | VAF 34/367 reads (9%) | catalogued as rs1471701176; called by muse, mutect2
- CDKAL1 | c.1104A>G p.G368= | Silent (SNP) | VAF 65/377 reads (17%) | called by muse, mutect2, varscan2
- CDT1 | c.630C>T p.R210= | Silent (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- CLCN1 | c.2100G>T p.A700= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs747257219; called by muse, mutect2, varscan2
- CLRN1 | c.321C>T p.I107= (on ENST00000327047 / NM_174878.3; = p.I31= on NM_052995.2) | Silent (SNP) | VAF 135/712 reads (19%) | catalogued as COSV55805979; called by muse, mutect2, varscan2
- CNOT9 | c.414C>T p.T138= | Silent (SNP) | VAF 34/408 reads (8%) | called by muse, mutect2
- CNP | c.624C>T p.V208= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs782373869; called by muse, mutect2, varscan2
- CRHR2 | c.345C>A p.I115= | Silent (SNP) | VAF 29/143 reads (20%) | called by muse, mutect2, varscan2
- CSMD1 | c.10032T>A p.T3344= (on ENST00000520002; = p.T3343= on NM_033225.6) | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- CSMD1 | c.3003C>A p.T1001= (on ENST00000520002; = p.T1000= on NM_033225.6) | Silent (SNP) | VAF 126/652 reads (19%) | catalogued as rs751657255, COSV59288299; called by muse, varscan2
- CSMD3 | c.2379G>T p.G793= (on ENST00000297405 / NM_001363185.1; = p.G689= on NM_052900.3) | Silent (SNP) | VAF 63/416 reads (15%) | catalogued as COSV52170385, COSV52317130; called by muse, mutect2, varscan2
- CXCR1 | c.1050C>G p.L350= | Silent (SNP) | VAF 23/454 reads (5%) | called by muse, mutect2
- DNAJB5 | c.348C>T p.R116= | Silent (SNP) | VAF 42/628 reads (7%) | called by muse, mutect2
- DNMT3L | c.378C>T p.V126= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as rs149547612; called by muse, mutect2, varscan2
- DOC2B | c.624C>T p.I208= | Silent (SNP) | VAF 17/147 reads (12%) | called by muse, mutect2, varscan2
- DPP7 | c.252C>T p.F84= | Silent (SNP) | VAF 33/165 reads (20%) | catalogued as rs1444397187; called by muse, mutect2, varscan2
- EEF1A1 | c.1248A>C p.S416= | Silent (SNP) | VAF 32/223 reads (14%) | called by muse, mutect2, varscan2
- EGLN3 | c.342C>A p.V114= | Silent (SNP) | VAF 54/286 reads (19%) | catalogued as rs776151085; called by muse, mutect2, varscan2
- EPOP | c.1089C>T p.V363= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- ERCC8 | c.144C>T p.T48= | Silent (SNP) | VAF 35/489 reads (7%) | called by muse, mutect2
- FAM120A | c.948C>T p.D316= | Silent (SNP) | VAF 62/483 reads (13%) | called by muse, mutect2, varscan2
- FANCM | c.6066C>T p.I2022= | Silent (SNP) | VAF 27/419 reads (6%) | catalogued as COSV57506330; called by muse, mutect2
- FAT4 | c.1032G>T p.L344= | Silent (SNP) | VAF 18/203 reads (9%) | catalogued as rs755511159; called by muse, mutect2
- FBH1 | c.918G>T p.V306= (on ENST00000362091 / NM_178150.3; = p.V357= on NM_032807.4) | Silent (SNP) | VAF 26/146 reads (18%) | called by muse, mutect2, varscan2
- FBXL4 | c.1041C>G p.V347= | Silent (SNP) | VAF 30/482 reads (6%) | called by muse, mutect2
- FLT3 | c.2097T>C p.L699= | Silent (SNP) | VAF 41/189 reads (22%) | called by muse, mutect2, varscan2
- FRYL | c.8898A>C p.I2966= | Silent (SNP) | VAF 150/934 reads (16%) | called by muse, mutect2, varscan2
- GPR52 | c.975G>T p.R325= | Silent (SNP) | VAF 34/366 reads (9%) | called by muse, mutect2
- GRM6 | c.588C>A p.P196= | Silent (SNP) | VAF 26/221 reads (12%) | catalogued as COSV51438814; called by muse, mutect2, varscan2
- H2AC16 | c.129G>T p.R43= | Silent (SNP) | VAF 15/188 reads (8%) | called by muse, mutect2
- HACD1 | c.609T>C p.Y203= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs915534175; called by muse, mutect2
- HIPK4 | c.477C>T p.F159= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs745473915, COSV52519032; called by muse, varscan2
- IP6K2 | c.762G>T p.V254= | Silent (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- ITGB3 | c.1851G>T p.P617= | Silent (SNP) | VAF 68/411 reads (17%) | called by muse, mutect2, varscan2
- JUP | c.762C>A p.L254= | Silent (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- KCNMA1 | c.3435C>T p.L1145= (on ENST00000286628 / NM_001161352.2; = p.L1087= on NM_002247.4) | Silent (SNP) | VAF 53/450 reads (12%) | catalogued as rs1449275813, COSV54271055; called by muse, mutect2, varscan2
- KCNMA1 | c.3333G>T p.A1111= (on ENST00000286628 / NM_001161352.2; = p.A1053= on NM_002247.4) | Silent (SNP) | VAF 62/403 reads (15%) | catalogued as rs200045097, COSV54227798; called by muse, mutect2, varscan2
- KCNS2 | c.630C>A p.P210= | Silent (SNP) | VAF 39/278 reads (14%) | catalogued as COSV54637710; called by muse, mutect2, varscan2
- KIAA0100 | c.6186G>C p.L2062= | Silent (SNP) | VAF 24/364 reads (7%) | called by muse, mutect2
- KPNA5 | c.894C>G p.V298= | Silent (SNP) | VAF 41/259 reads (16%) | called by muse, mutect2, varscan2
- LCN1 | c.111G>A p.L37= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- LRP2 | c.3735G>A p.P1245= | Silent (SNP) | VAF 40/242 reads (17%) | catalogued as COSV55569092, COSV55576915; called by muse, mutect2, varscan2
- LRRC8A | c.1722C>T p.I574= | Silent (SNP) | VAF 13/202 reads (6%) | catalogued as rs1047757022, COSV99035190; called by muse, mutect2
- MUC5AC | c.1179G>A p.K393= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs368207095; called by muse, mutect2, varscan2
- MUC6 | c.1944C>A p.V648= | Silent (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- NAALADL1 | c.2160C>T p.L720= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV57248232; called by muse, mutect2, varscan2
- NCAM2 | c.2259C>T p.L753= | Silent (SNP) | VAF 41/387 reads (11%) | catalogued as rs1411982097, COSV53080351; called by muse, mutect2, varscan2
- NFATC4 | c.1305A>G p.T435= | Silent (SNP) | VAF 74/450 reads (16%) | called by muse, mutect2, varscan2
- NOTCH4 | c.4426C>A p.R1476= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV66679139; called by muse, mutect2, varscan2
- NPTX1 | c.741G>T p.L247= | Silent (SNP) | VAF 69/343 reads (20%) | catalogued as rs1467163802; called by muse, mutect2, varscan2
- NUP160 | c.1710C>A p.P570= | Silent (SNP) | VAF 48/348 reads (14%) | called by muse, mutect2, varscan2
- OPTN | c.18C>T p.L6= | Silent (SNP) | VAF 31/490 reads (6%) | called by muse, mutect2
- OR51G2 | c.597C>A p.A199= | Silent (SNP) | VAF 40/349 reads (11%) | called by muse, mutect2, varscan2
- OR52A5 | c.738C>A p.A246= | Silent (SNP) | VAF 84/387 reads (22%) | catalogued as rs768051712; called by muse, mutect2, varscan2
- OR8K1 | c.582C>G p.L194= | Silent (SNP) | VAF 32/369 reads (9%) | catalogued as COSV54401334; called by muse, mutect2
- OSBPL5 | c.1110G>C p.L370= | Silent (SNP) | VAF 13/140 reads (9%) | called by muse, mutect2
- OTC | c.375G>C p.T125= | Silent (SNP) | VAF 86/511 reads (17%) | catalogued as COSV50003764; called by muse, varscan2
- OTUD4 | c.1332A>T p.P444= (on ENST00000447906 / NM_001366057.1; = p.P379= on NM_001102653.1) | Silent (SNP) | VAF 86/850 reads (10%) | called by muse, mutect2, varscan2
- PARP12 | c.330G>A p.K110= | Silent (SNP) | VAF 20/242 reads (8%) | catalogued as COSV54936640; called by muse, mutect2
- PCDHGA9 | c.204T>C p.S68= | Silent (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- PHF1 | c.1002G>C p.R334= | Silent (SNP) | VAF 11/186 reads (6%) | called by muse, mutect2
- PKDREJ | c.3039G>A p.V1013= | Silent (SNP) | VAF 83/286 reads (29%) | called by muse, mutect2, varscan2
- PLEC | c.9912C>T p.T3304= (on ENST00000322810 / NM_201380.4; = p.T3194= on NM_000445.5) | Silent (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- POLA1 | c.3153A>G p.K1051= | Silent (SNP) | VAF 96/502 reads (19%) | catalogued as rs1380430145; called by muse, mutect2, varscan2
- PTCH1 | c.1857C>A p.V619= | Silent (SNP) | VAF 56/432 reads (13%) | called by muse, mutect2, varscan2
- PTK6 | c.744G>C p.L248= | Silent (SNP) | VAF 17/121 reads (14%) | called by muse, mutect2, varscan2
- PXDNL | c.1704C>T p.Y568= | Silent (SNP) | VAF 70/349 reads (20%) | catalogued as rs950735336, COSV62480026; called by muse, mutect2, varscan2
- RANBP10 | c.132C>G p.P44= | Silent (SNP) | VAF 24/240 reads (10%) | called by muse, mutect2
- RDH14 | c.360C>G p.R120= | Silent (SNP) | VAF 14/199 reads (7%) | catalogued as rs1477399247; called by muse, mutect2
- RNF213 | c.7398G>A p.E2466= | Silent (SNP) | VAF 59/768 reads (8%) | catalogued as rs746424283, COSV100301568; called by muse, mutect2
- SGCE | c.1278C>T p.F426= (on ENST00000647096; = p.F390= on NM_003919.3) | Silent (SNP) | VAF 44/654 reads (7%) | called by muse, mutect2
- SIGLEC9 | c.241C>A p.R81= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as COSV51583045; called by muse, mutect2, varscan2
- SLC12A5 | c.2040C>G p.L680= (on ENST00000454036 / NM_001134771.2; = p.L657= on NM_020708.5) | Silent (SNP) | VAF 19/216 reads (9%) | called by muse, mutect2
- SLC26A9 | c.1350C>G p.T450= | Silent (SNP) | VAF 37/467 reads (8%) | catalogued as COSV61604147; called by muse, mutect2
- SLC2A1 | c.1248C>T p.F416= | Silent (SNP) | VAF 45/490 reads (9%) | called by muse, mutect2
- SLC30A8 | c.363G>C p.L121= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as COSV69975074; called by muse, mutect2, varscan2
- SMIM26 | c.243C>T p.L81= | Silent (SNP) | VAF 60/652 reads (9%) | called by muse, mutect2
- SNAP91 | c.2469A>T p.S823= | Silent (SNP) | VAF 33/219 reads (15%) | catalogued as COSV52126610; called by muse, mutect2, varscan2
- SOWAHB | c.1008C>G p.L336= | Silent (SNP) | VAF 24/246 reads (10%) | called by muse, mutect2
- SPATC1 | c.1431A>G p.P477= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as rs782524315; called by muse, mutect2, varscan2
- SRRM2 | c.3156C>G p.V1052= | Silent (SNP) | VAF 50/238 reads (21%) | catalogued as rs781687507; called by muse, mutect2, varscan2
- TERT | c.795G>T p.P265= | Silent (SNP) | VAF 63/195 reads (32%) | called by muse, mutect2, varscan2
- TMEM131L | c.4167C>T p.S1389= | Silent (SNP) | VAF 35/215 reads (16%) | called by muse, mutect2, varscan2
- TMEM200A | c.36C>T p.A12= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs368801042; called by muse, mutect2
- TRPM1 | c.2844C>G p.V948= | Silent (SNP) | VAF 61/521 reads (12%) | catalogued as rs748497887; called by muse, mutect2, varscan2
- TTLL9 | c.1272G>A p.L424= | Silent (SNP) | VAF 45/258 reads (17%) | called by muse, mutect2, varscan2
- TUFT1 | c.201G>T p.L67= | Silent (SNP) | VAF 36/584 reads (6%) | called by muse, mutect2
- URB1 | c.6456G>T p.L2152= | Silent (SNP) | VAF 21/107 reads (20%) | called by muse, mutect2, varscan2
- URB2 | c.1203A>T p.A401= | Silent (SNP) | VAF 23/134 reads (17%) | called by muse, mutect2, varscan2
- VWA5B2 | c.1623G>A p.L541= | Silent (SNP) | VAF 33/193 reads (17%) | catalogued as rs968888173; called by muse, mutect2, varscan2
- WDFY3 | c.1194C>T p.F398= | Silent (SNP) | VAF 36/380 reads (9%) | catalogued as rs758339183; called by muse, mutect2
- ZFHX3 | c.3828C>T p.S1276= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs939051193; called by muse, mutect2, varscan2
- ZNF469 | c.9420G>T p.A3140= (on ENST00000437464; = p.A3168= on NM_001367624.2) | Silent (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- ZNF48 | c.843C>T p.G281= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, varscan2
- ZNF507 | c.1020G>A p.Q340= | Silent (SNP) | VAF 33/465 reads (7%) | catalogued as COSV61329657; called by muse, mutect2
- ZNF696 | c.417C>T p.D139= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs761842581; called by muse, mutect2, varscan2
- ZNF729 | c.948A>T p.A316= | Silent (SNP) | VAF 61/287 reads (21%) | called by muse, mutect2, varscan2
- ZNF776 | c.1425C>G p.L475= | Silent (SNP) | VAF 34/654 reads (5%) | called by muse, mutect2
- ACOX1 | c.431-2798G>A | Intron (SNP) | VAF 29/420 reads (7%) | catalogued as rs372320683; called by muse, mutect2
- AFDN | chr6:167826310 C>T | 5'Flank (SNP) | VAF 65/408 reads (16%) | catalogued as rs768970913; called by muse, mutect2, varscan2
- ALDH1L1 | c.128-785del | Intron (DEL) | VAF 55/204 reads (27%) | called by mutect2, pindel, varscan2
- AMDHD2 | c.862+23G>T | Intron (SNP) | VAF 24/300 reads (8%) | called by muse, mutect2
- ANAPC15 | chr11:72107402 G>A | 3'Flank (SNP) | VAF 21/98 reads (21%) | called by muse, mutect2, varscan2
- APH1B | c.113+557G>A | Intron (SNP) | VAF 19/365 reads (5%) | called by muse, mutect2
- API5 | c.*91G>A | 3'UTR (SNP) | VAF 24/452 reads (5%) | catalogued as rs1435589014; called by muse, mutect2
- ATP6V1E1 | c.-24C>A | 5'UTR (SNP) | VAF 26/216 reads (12%) | called by muse, mutect2, varscan2
- BCHE | c.1685-5226T>G | Intron (SNP) | VAF 23/292 reads (8%) | called by muse, mutect2
- BSCL2 | chr11:62707304 G>C | 5'Flank (SNP) | VAF 50/800 reads (6%) | catalogued as rs796912815; called by muse, mutect2
- C12orf76 | n.665-5952C>G | Intron (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- C2orf68 | c.226+113C>G | Intron (SNP) | VAF 20/241 reads (8%) | catalogued as rs754086883; called by muse, mutect2
- C7orf65 | n.471G>A | RNA (SNP) | VAF 12/98 reads (12%) | called by muse, varscan2
- C8orf31 | n.387C>T | RNA (SNP) | VAF 20/322 reads (6%) | called by muse, mutect2
- CCDC162P | n.1876G>C | RNA (SNP) | VAF 28/294 reads (10%) | called by muse, mutect2
- CCDC78 | c.60+26C>T | Intron (SNP) | VAF 19/156 reads (12%) | called by muse, mutect2, varscan2
- CCM2 | chr7:44999817 C>T | 5'Flank (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2
- CCNT2 | c.539+18C>G | Intron (SNP) | VAF 29/436 reads (7%) | called by muse, mutect2
- CNKSR1 | c.392+40C>A | Intron (SNP) | VAF 26/294 reads (9%) | called by muse, mutect2
- CNKSR2 | c.520-16G>T | Intron (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2
- COX10 | c.499+17A>T | Intron (SNP) | VAF 27/190 reads (14%) | called by muse, mutect2, varscan2
- CREB5 | chr7:28409804 C>A | 5'Flank (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2
- CXXC1 | c.1525-11C>G | Intron (SNP) | VAF 16/196 reads (8%) | called by muse, mutect2
- DYNC1H1 | c.6619-21C>G | Intron (SNP) | VAF 60/387 reads (16%) | called by muse, mutect2, varscan2
- ENPP2 | c.1781-1340G>C | Intron (SNP) | VAF 33/359 reads (9%) | catalogued as COSV99030193; called by muse, mutect2
- FOXP2 | c.1267-1566G>A | Intron (SNP) | VAF 14/407 reads (3%) | called by muse, mutect2
- GABRA2 | c.1059+5612C>A | Intron (SNP) | VAF 14/352 reads (4%) | called by muse, mutect2
- GABRG2 | c.1249-1302C>T | Intron (SNP) | VAF 22/294 reads (7%) | catalogued as rs1258941239; called by muse, mutect2
- GAS2 | c.409+4936G>T | Intron (SNP) | VAF 34/249 reads (14%) | called by muse, varscan2
- GFI1B | c.649-21G>T | Intron (SNP) | VAF 23/129 reads (18%) | called by muse, mutect2, varscan2
- GNB5 | c.864-449G>A | Intron (SNP) | VAF 22/420 reads (5%) | catalogued as COSV55897654; called by muse, mutect2
- GP6 | c.*497C>G | 3'UTR (SNP) | VAF 58/854 reads (7%) | catalogued as COSV100117792; called by muse, mutect2
- HACL1 | c.*16G>A | 3'UTR (SNP) | VAF 70/449 reads (16%) | called by muse, mutect2, varscan2
- HAUS7 | chrX:153470932 C>T | 5'Flank (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- HDAC7 | c.1562-669C>T | Intron (SNP) | VAF 23/227 reads (10%) | called by muse, mutect2
- IPO5 | c.-152G>C | 5'UTR (SNP) | VAF 40/375 reads (11%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.632C>T | RNA (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2
- KIRREL1 | c.*1972G>T | 3'UTR (SNP) | VAF 17/123 reads (14%) | called by muse, mutect2, varscan2
- KIRREL1 | c.*1973G>T | 3'UTR (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2
- LCN12 | c.550+56G>C | Intron (SNP) | VAF 19/232 reads (8%) | called by muse, mutect2
- LEKR1 | c.*720G>T | 3'UTR (SNP) | VAF 89/534 reads (17%) | catalogued as COSV62960914; called by muse, mutect2, varscan2
- LEKR1 | c.*1285A>C | 3'UTR (SNP) | VAF 32/304 reads (11%) | called by muse, mutect2, varscan2
- LHB | c.16-32C>G | Intron (SNP) | VAF 11/162 reads (7%) | called by muse, mutect2
- LITAF | c.*175A>T | 3'UTR (SNP) | VAF 103/743 reads (14%) | called by muse, mutect2, varscan2
- LRR1 | c.184-761G>T | Intron (SNP) | VAF 107/472 reads (23%) | called by muse, mutect2, varscan2
- LRRC6 | c.1144+1626G>A | Intron (SNP) | VAF 21/282 reads (7%) | called by muse, mutect2
- LTBR | c.668-533C>T | Intron (SNP) | VAF 8/75 reads (11%) | catalogued as rs1026843815, COSV57439763; called by muse, mutect2, varscan2
- LTBR | c.668-532G>T | Intron (SNP) | VAF 8/72 reads (11%) | called by mutect2, varscan2
- LYPD6B | c.5+29879C>T | Intron (SNP) | VAF 62/616 reads (10%) | catalogued as rs1329624806; called by muse, mutect2
- MOXD1 | c.264+8931G>T | Intron (SNP) | VAF 39/343 reads (11%) | called by muse, mutect2, varscan2
- OBSCN | chr1:228204117 G>T | 5'Flank (SNP) | VAF 7/149 reads (5%) | called by muse, mutect2
- PCF11 | c.2092+10G>A | Intron (SNP) | VAF 40/240 reads (17%) | called by muse, mutect2, varscan2
- PIPSL | n.2049A>G | RNA (SNP) | VAF 61/315 reads (19%) | called by muse, mutect2, varscan2
- PIPSL | n.2048C>A | RNA (SNP) | VAF 64/316 reads (20%) | called by muse, mutect2, varscan2
- PKP4 | c.3256+36G>C | Intron (SNP) | VAF 52/650 reads (8%) | catalogued as rs1329496655, COSV104418715; called by muse, mutect2
- POLR3H | c.*7G>A | 3'UTR (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- POTEC | c.1126+1497C>A | Intron (SNP) | VAF 98/505 reads (19%) | called by muse, mutect2, varscan2
- PPP2R2B | c.-3G>T | 5'UTR (SNP) | VAF 31/395 reads (8%) | catalogued as COSV100355647; called by muse, mutect2
- PRMT1 | c.759+17G>T | Intron (SNP) | VAF 20/87 reads (23%) | called by muse, mutect2, varscan2
- PRR12 | chr19:49594865 C>G | 5'Flank (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- PSG4 | c.65-588T>G | Intron (SNP) | VAF 12/133 reads (9%) | catalogued as rs1204721634; called by muse, mutect2
- RAB18 | c.*370G>T | 3'UTR (SNP) | VAF 109/677 reads (16%) | called by muse, mutect2, varscan2
- RBFOX1 | c.931-5193T>A | Intron (SNP) | VAF 62/415 reads (15%) | called by muse, mutect2, varscan2
- RTF2 | c.-26C>T | 5'UTR (SNP) | VAF 27/151 reads (18%) | called by muse, mutect2, varscan2
- SLC1A7 | c.1032-12_1032-10dup | Intron (INS) | VAF 14/138 reads (10%) | called by mutect2, pindel
- ST20-MTHFS | c.-12+446C>T | Intron (SNP) | VAF 12/105 reads (11%) | catalogued as rs773540286; called by muse, mutect2, varscan2
- SUMO1 | c.238-671C>T | Intron (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- TGM4 | c.-12G>C | 5'UTR (SNP) | VAF 16/244 reads (7%) | called by muse, mutect2
- TLDC2 | c.-4G>T | 5'UTR (SNP) | VAF 19/208 reads (9%) | catalogued as COSV99455703; called by muse, mutect2
- TNNI3 | c.24+22G>T | Intron (SNP) | VAF 15/86 reads (17%) | catalogued as COSV61277079; called by muse, mutect2, varscan2
- TNNT3 | c.116-44G>A | Intron (SNP) | VAF 48/215 reads (22%) | called by muse, mutect2, varscan2
- TNNT3 | c.322-39C>A | Intron (SNP) | VAF 78/354 reads (22%) | catalogued as rs376479302; called by muse, mutect2, varscan2
- TRPA1 | c.3150-40G>A | Intron (SNP) | VAF 24/282 reads (9%) | called by muse, mutect2
- TRPM4 | c.1264-16C>T | Intron (SNP) | VAF 29/331 reads (9%) | called by muse, mutect2
- TXLNB | c.1077+76C>A | Intron (SNP) | VAF 42/267 reads (16%) | called by muse, mutect2, varscan2
- UQCRB | c.*516G>C | 3'UTR (SNP) | VAF 19/256 reads (7%) | called by muse, mutect2
- USP28 | c.535-985C>G | Intron (SNP) | VAF 43/500 reads (9%) | called by muse, mutect2
- ZSWIM8 | c.-181G>T | 5'UTR (SNP) | VAF 13/197 reads (7%) | catalogued as COSV65708644; called by muse, mutect2
